Somatic mutation profile of tumor specimen TCGA-BQ-5880-01A (aliquot TCGA-BQ-5880-01A-11D-1589-08) from TCGA case TCGA-BQ-5880, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 79.5 years (29,053 days).
Specimen TCGA-BQ-5880-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55d6685f-b9a7-45f7-a058-fd1863811b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5880-11A (Solid Tissue Normal), aliquot TCGA-BQ-5880-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0407a2f3-34de-4ba4-bcdd-7cc58723366e

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 28, Silent 9, Frame Shift Del 7, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.3461T>A p.V1154D | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569351534, COSV59128377; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV62550437; called by muse, mutect2, varscan2
- ARID1A | c.6593T>C p.F2198S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61373920; called by muse, mutect2, varscan2
- BUB1 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as rs781312045, COSV57061975; called by muse, mutect2, varscan2
- CAD | c.4337C>A p.A1446D | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.994); catalogued as COSV53024742; called by muse, mutect2, varscan2
- CUBN | c.9035C>T p.P3012L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs143741363, COSV100912355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.5434A>G p.I1812V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776062089, COSV70227278; called by muse, mutect2, varscan2
- DPAGT1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62614112, COSV62614795; called by muse, mutect2, varscan2
- FASN | c.5321T>G p.L1774R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60751865; called by muse, mutect2, varscan2
- GXYLT2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as rs142024018, COSV67473693; called by muse, mutect2, varscan2
- IGSF3 | c.2317G>A p.E773K (on ENST00000369486 / NM_001007237.3; = p.E793K on NM_001542.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs761730940, COSV59588234; called by muse, mutect2, varscan2
- MACF1 | c.2977C>A p.L993I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV58364621; called by muse, mutect2, varscan2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | catalogued as rs776720499; called by mutect2, pindel
- MYO18B | c.6376C>T p.Q2126* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV59128865; called by muse, mutect2, varscan2
- MYO9B | c.4512G>T p.Q1504H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV68277797, COSV68282122; called by muse, mutect2, varscan2
- NFXL1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs1481989277, COSV61198329; called by muse, mutect2, varscan2
- NTNG1 | c.962C>A p.T321N | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53965452; called by muse, mutect2, varscan2
- NUP214 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63908324; called by muse, mutect2, varscan2
- PREX2 | c.3950T>C p.L1317P | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55750443, COSV55758131; called by muse, mutect2
- RBAK | c.1649A>T p.E550V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100806770; called by muse, mutect2, varscan2
- RFX7 | c.2397G>C p.Q799H (on ENST00000559447 / NM_001368074.1; = p.Q896H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV57961075; called by muse, mutect2, varscan2
- SELL | c.422G>A p.C141Y (on ENST00000650983; = p.C128Y on NM_000655.5) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52550561; called by muse, mutect2, varscan2
- SLC4A4 | c.3102T>A p.S1034= (on ENST00000264485 / NM_001098484.3; = p.S990= on NM_003759.4) | Splice Region (SNP) | VAF 31/182 reads (17%) | catalogued as COSV52621345; called by muse, mutect2, varscan2
- SLMAP | c.1765G>T p.A589S (on ENST00000428312 / NM_001377924.1; = p.A651S on NM_007159.5) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.06); catalogued as rs1272141340, COSV55845476; called by muse, mutect2, varscan2
- UBE2R2 | c.331T>A p.S111T | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV54288367; called by muse, mutect2, varscan2
- UMODL1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV68555204; called by muse, mutect2, varscan2
- VPS50 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.558); catalogued as COSV58506278; called by muse, mutect2, varscan2
- WSCD2 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54579669; called by muse, mutect2, varscan2
- ZNF266 | c.1234A>C p.K412Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV63221672; called by muse, mutect2, varscan2
- ZNF521 | c.1576T>G p.S526A | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs371804263, COSV100833133; called by muse, mutect2, varscan2
- ZNF561 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57177454; called by muse, mutect2, varscan2
- CYFIP1 | c.548del p.N183Tfs*48 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- GBE1 | c.504del p.D169Ifs*3 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- KMT2D | c.3813_3814del p.L1272Vfs*13 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | called by mutect2, pindel, varscan2
- KRTAP10-7 | c.173C>G p.T58S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- LGR4 | c.1934dup p.L645Ffs*40 | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- PSD2 | c.882del p.L295Wfs*65 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | called by mutect2, pindel, varscan2
- STAG3 | c.171del p.R58Afs*3 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- STAT5A | c.1280_1305del p.A427Dfs*10 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel
- HIVEP3 | c.6588C>G p.P2196= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV56011359; called by muse, mutect2, varscan2
- LAMA1 | c.2382T>C p.P794= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101057695; called by muse, mutect2, varscan2
- OR8J3 | c.729G>A p.S243= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs774862778, COSV56879581, COSV56879736; called by muse, mutect2, varscan2
- RDH11 | c.576C>T p.G192= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs764879646, COSV67282519; called by muse, mutect2, varscan2
- RGP1 | c.495G>A p.Q165= | Silent (SNP) | VAF 80/376 reads (21%) | catalogued as COSV100960221, COSV65239061; called by muse, mutect2, varscan2
- SLC26A8 | c.1002G>A p.T334= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs547194034, COSV62885036; called by muse, mutect2, varscan2
- SP4 | c.132G>A p.Q44= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV56021396; called by muse, mutect2, varscan2
- TTI1 | c.3117A>T p.P1039= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV65060933; called by muse, mutect2
- ZNF236 | c.2718C>T p.S906= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs1169059737, COSV53484294; called by muse, mutect2, varscan2
